Somatic mutation profile of tumor specimen 0DG38D from CCDI case PBBSHC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,595 days).
Specimen 0DG38D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8273d08f-15e8-4069-836a-aca2c06936ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG385 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f0b4e1b-4160-4191-8c3b-ad8f0db6734f

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Intron 4, Frame Shift Del 3, RNA 1, 5'Flank 1, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APPL1 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 370/429 reads (86%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); catalogued as rs762717192; called by muse, mutect2, varscan2
- FRMD3 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 21/618 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs1302199141; called by muse, mutect2
- GMIP | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 274/657 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.64); catalogued as rs763004177; called by muse, mutect2, varscan2
- ITK | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs745561238; called by muse, mutect2, varscan2
- ITPKC | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 59/354 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99648781; called by muse, mutect2, varscan2
- SNAI1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 356/823 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54864373; called by muse, mutect2, varscan2
- TAF1C | c.1787A>G p.Y596C | Missense Mutation (SNP) | VAF 316/797 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.891); catalogued as rs1334997798; called by muse, mutect2, varscan2
- TAS2R1 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 267/639 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs200371021; called by mutect2, varscan2
- ZGRF1 | c.3326T>C p.L1109P | Missense Mutation (SNP) | VAF 216/539 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV58408076; called by muse, mutect2, varscan2
- AKAP3 | c.1409A>C p.K470T | Missense Mutation (SNP) | VAF 152/441 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- ANKRD12 | c.3226_3235del p.M1076Vfs*6 | Frame Shift Del (DEL) | VAF 223/728 reads (31%) | called by mutect2, varscan2
- CAPN15 | c.2425G>T p.A809S | Missense Mutation (SNP) | VAF 54/672 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2
- CELF4 | c.1038del p.Q347Rfs*53 | Frame Shift Del (DEL) | VAF 138/262 reads (53%) | called by mutect2, varscan2
- CELF4 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 139/260 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by mutect2, varscan2
- CFAP69 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 179/462 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPXCR1 | c.4A>T p.S2C | Missense Mutation (SNP) | VAF 176/613 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- FLG | c.11137C>G p.Q3713E | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- GNPTAB | c.2771G>C p.G924A | Missense Mutation (SNP) | VAF 82/425 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HES6 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 333/715 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFI27 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 289/357 reads (81%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- KL | c.2024A>G p.Q675R | Missense Mutation (SNP) | VAF 433/1073 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR10AC1 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 341/1015 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR4M1 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 126/392 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by mutect2, varscan2
- OR7A10 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 200/546 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- PCOLCE | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 263/600 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDIA2 | c.279G>C p.M93I | Missense Mutation (SNP) | VAF 346/793 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNN | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PPIAL4G | c.254A>T p.D85V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRR32 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 350/1251 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SCN7A | c.980T>A p.I327K | Missense Mutation (SNP) | VAF 291/680 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TP53 | c.362_375+6del p.X121_splice | Splice Site (DEL) | VAF 178/211 reads (84%) | called by mutect2, varscan2
- TRIM49B | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 36/779 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- XIRP2 | c.8868del p.R2957Efs*77 (on ENST00000628543; = p.R3132Efs*77 on NM_152381.6) | Frame Shift Del (DEL) | VAF 315/797 reads (40%) | called by mutect2, varscan2
- CCDC124 | c.267G>A p.V89= | Silent (SNP) | VAF 164/375 reads (44%) | catalogued as rs953953979; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 15/400 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- CHST5 | c.1011A>C p.P337= | Silent (SNP) | VAF 368/825 reads (45%) | called by muse, mutect2, varscan2
- IGSF22 | c.1206G>A p.E402= | Silent (SNP) | VAF 250/582 reads (43%) | called by muse, mutect2, varscan2
- IRAG2 | c.2226A>G p.E742= | Silent (SNP) | VAF 231/609 reads (38%) | called by muse, mutect2, varscan2
- KATNBL1 | c.681T>C p.L227= | Silent (SNP) | VAF 288/648 reads (44%) | called by muse, mutect2, varscan2
- KIAA0100 | c.6345C>T p.F2115= | Silent (SNP) | VAF 346/793 reads (44%) | catalogued as rs1218183436; called by muse, mutect2, varscan2
- NCOA3 | c.969T>C p.Y323= | Silent (SNP) | VAF 324/785 reads (41%) | called by muse, mutect2, varscan2
- TMEM229A | c.93G>T p.A31= | Silent (SNP) | VAF 151/400 reads (38%) | catalogued as rs752114366; called by muse, mutect2, varscan2
- UBAP2L | c.2931C>T p.G977= | Silent (SNP) | VAF 260/739 reads (35%) | catalogued as rs947386916; called by muse, mutect2, varscan2
- XXYLT1 | c.537T>C p.D179= | Silent (SNP) | VAF 377/920 reads (41%) | called by muse, mutect2, varscan2
- C11orf97 | c.*12T>A | 3'UTR (SNP) | VAF 307/654 reads (47%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- FLVCR1 | c.1196+51T>A | Intron (SNP) | VAF 144/305 reads (47%) | called by muse, mutect2, varscan2
- METAP1 | chr4:98995689 C>G | 5'Flank (SNP) | VAF 23/45 reads (51%) | catalogued as rs1307260513; called by muse, mutect2
- MST1L | n.2076G>C | RNA (SNP) | VAF 106/1867 reads (6%) | called by muse, mutect2
- PLP2 | c.345+13G>T | Intron (SNP) | VAF 287/336 reads (85%) | called by muse, mutect2, varscan2
- RENBP | c.-3G>T | 5'UTR (SNP) | VAF 231/982 reads (24%) | called by muse, mutect2, varscan2
- WDR46 | c.1735-12T>C | Intron (SNP) | VAF 97/199 reads (49%) | called by muse, mutect2, varscan2
